Somatic mutation profile of tumor specimen 0DRCK2 from CCDI case PBCFGM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.0 years (362 days).
Specimen 0DRCK2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7a648a5-e045-4188-ba65-daaeee806169.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRCJW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b358a0a9-cbe4-4937-89c9-4e68b92354dd

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC2 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 53/359 reads (15%) | catalogued as rs1064796511; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC2 | c.4646A>G p.Y1549C | Missense Mutation (SNP) | VAF 63/392 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs45517355, CM981955; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ABR | c.681C>T p.L227= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1012167450; called by muse, mutect2, varscan2
- CLDN5 | c.450G>A p.P150= (on ENST00000618236 / NM_001363066.2; = p.P235= on NM_003277.4) | Silent (SNP) | VAF 59/317 reads (19%) | called by muse, mutect2, varscan2
